Somatic mutation profile of tumor specimen 0DI6L4 from CCDI case PBBVKX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,984 days).
Specimen 0DI6L4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8844afd7-3db5-4590-a783-2b9922771ca2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI6KJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c12c1400-da19-4c7a-be49-8712d29841c3

The open-access MAF lists 7 somatic variants for this specimen: 7 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MUC12 | c.13559G>A p.R4520H (on ENST00000379442; = p.R4377H on NM_001164462.1) | Missense Mutation (SNP) | VAF 183/381 reads (48%) | SIFT tolerated (0.61); catalogued as rs112087460; called by muse, mutect2, varscan2
- PCDHB10 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 20/650 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.766); catalogued as rs1563953222, COSV53378197; called by muse, mutect2
- PKP2 | c.899C>A p.T300K | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs553098424, COSV50749979; called by muse, mutect2, varscan2
- MAGEC3 | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 31/914 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDH1 | c.2521G>A p.D841N | Missense Mutation (SNP) | VAF 26/660 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- PTPN18 | c.958C>G p.L320V | Missense Mutation (SNP) | VAF 25/744 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.162); called by muse, mutect2
- TONSL | c.323G>A p.R108K | Missense Mutation (SNP) | VAF 46/874 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
